Somatic mutation profile of tumor specimen TARGET-10-PANTTB-09A (aliquot TARGET-10-PANTTB-09A-01D) from TARGET case TARGET-10-PANTTB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,705 days).
Specimen TARGET-10-PANTTB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f47f34b5-5be8-43f8-8668-2b878f5ae8ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTTB-14A (Bone Marrow Normal), aliquot TARGET-10-PANTTB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29cc2c56-2915-4ee4-858a-8396400001e2

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 2, 3'UTR 1, Frame Shift Ins 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CABP7 | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772614797; called by muse, mutect2, varscan2
- GJA3 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs375041482, COSV53834889; called by muse, mutect2, varscan2
- KMT2D | c.15781C>T p.Q5261* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV56489777; called by muse, mutect2, varscan2
- NOVA1 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV57481839; called by muse, mutect2, varscan2
- PCDHB5 | c.2365C>T p.R789W | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV50654970; called by muse, mutect2, varscan2
- PPP1R1C | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.726); catalogued as COSV54715516; called by muse, mutect2, varscan2
- RAMP3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.86); catalogued as rs574497056, COSV54246881; called by muse, mutect2, varscan2
- SLC4A11 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs202020752; called by muse, mutect2, varscan2
- UBE2F | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs772665382; called by muse, mutect2, varscan2
- CA5B | c.807del p.E270Kfs*18 | Frame Shift Del (DEL) | VAF 54/56 reads (96%) | called by mutect2, varscan2
- CCDC40 | c.3055_3060dup p.L1019_E1020dup | In Frame Ins (INS) | VAF 31/75 reads (41%) | called by mutect2, varscan2
- CERS3 | c.572_575dup p.L193Sfs*4 | Frame Shift Ins (INS) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- FATE1 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRPAP1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- OR1K1 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEX5 | c.1748T>C p.L583P (on ENST00000420616; = p.L575P on NM_000319.5) | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DQX1 | c.39C>T p.G13= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- GPR12 | c.633G>A p.A211= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs780499950, COSV67343995; called by muse, mutect2, varscan2
- LRRC4B | c.954C>T p.D318= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs769692046, COSV65350263; called by muse, mutect2, varscan2
- MLST8 | c.384C>T p.N128= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as rs758000683, COSV57030205; called by muse, mutect2, varscan2
- AQP2 | c.*222_*223insTTTATCCGCCCCCCAG | 3'UTR (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
